Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JI, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JI-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A LEFT KIDNEY, PARTIAL NEPHRECTOMY:
Renal cell carcinoma, papillary type, with necrosis, Fuhrman nuclear grade 3 of 4 (See Comment).
See Key Pathological Findings.

COMMENT: Immunohistochemical stains are performed with appropriate controls. The tumor cells are positive for AMACR (diffuse weak to strong), RCC (focal strong), and CK7 (focal weak) while negative for Ker903 and CK20. This immunoprofile supports the above diagnosis.

- B "DEEP MARGIN #1," RESECTION:
Renal cell carcinoma present at inked surgical margin.
- C "DEEP MARGIN #2," RESECTION:
Renal parenchyma, negative for carcinoma.
- D "RENAL VEIN THROMBUS," RESECTION:
Fragments of renal cell carcinoma.
- E "RENAL PARENCHYMAL DEEP MARGIN FINAL," RESECTION:
Renal parenchyma, negative for carcinoma.

*ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NOS C64.9
JW 4/28/14*

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Key Pathological Findings

Tumor type:	Renal cell carcinoma, papillary type, with necrosis.
Nuclear grade:	Fuhrman nuclear grade 3 of 4.
Pattern of growth:	Solid and papillary.
Tumor size:	6.5 cm.
Invasion through Renal capsule:	Not identified.
Invasion of Gerota's Fascia:	Not applicable.
Renal vein involvement:	Yes.
Surgical margins:	Renal parenchyma surgical resection margins, free of tumor. Per the procedure note, the renal vein thrombus was completely resected.
Non-neoplastic kidney:	Moderate chronic inflammation.
Adrenal gland:	Not applicable.
Lymph nodes:	Not applicable.
Pathologic stage:	pT3aNXMX.

Specimen(s) Received

- A LEFT PARTIAL NEPHRECTOMY FS

[page 2 of 3]
- B DEEP MARGIN #1 FS
- C DEEP MARGIN #2 FS
- D RENAL VEIN THROMBUS
- E RENAL PARENCHYMAL DEEP MARGIN FINAL FS

Clinical History

Left kidney mass.

Preoperative Diagnosis

Left kidney mass.

Intraoperative Consultation

FSA1. LEFT PARTIAL NEPHRECTOMY:
Inked margin is negative. Tumor is close to ink.

FSB1. DEEP MARGIN #1:
Tumor at inked margin.

FSC1. DEEP MARGIN #2:
Negative for tumor.

FSE1. RENAL PARENCHYMAL DEEP MARGIN FINAL:
Negative for tumor.

Comment: These frozen section diagnoses/results were communicated to and acknowledged by Dr.

I, _____, have performed the intraoperative consultations and issued the above diagnoses.

Gross Description

A. The specimen is received fresh labeled "left partial nephrectomy" and consists of a 62.9 gram, 6.5 x 6.5 x 5.5 cm partial kidney resection. The surgical margin is inked black. The capsule is smooth with a small amount of attached adipose tissue. The resection is largely replaced by a 6.5 x 6.5 x 5.5 cm, well-circumscribed, yellow, tan, congested mass with areas of necrosis. The mass abuts and distends the surgical margin and capsule. Abutting the mass is a 2.5 x 1.8 x 1.5 cm, soft, friable, tan mass, which extends to the surgical margin. There is a minimal amount of normal renal parenchyma. A representative section of the mass with margin is frozen (perpendicular section) and entirely submitted in FSA1. Additional representative sections are submitted as follows:

A2-A4: Mass with adjacent friable area

A5-A8: Composite section of mass including area adjacent normal parenchyma in A6

A9: Mass with capsule

B. The specimen is received fresh labeled "deep margin #1" and consists of a 4.2 x 2.5 x 2.5 cm partial kidney resection. The margin is inked black. The remaining surface has a thin membranous lining. The kidney has a 2.5 x 1.5 x 1.5 cm, soft, friable, tan congested mass. There is a small

[page 3 of 3]
amount of residual normal renal parenchyma. A representative section of the mass closest to the deep margin is frozen (perpendicular section) and entirely submitted in FSB1. Additional representative sections of renal parenchyma and mass are submitted in B2-B4.

C. The specimen is received fresh labeled "deep margin #2" and consists of a 1.5 x 0.8 x 0.6 cm portion of kidney. The deep margin is inked black. The tissue is sectioned (perpendicular sections), frozen, and entirely submitted in FSC1.

D. The specimen is received fresh labeled "renal vein thrombosis" and consists of a 2.5 x 1.5 x 1.0 cm aggregate of fragmented, soft, friable, gritty, red brown material. The tissue is entirely submitted in D1.

E. The specimen is received fresh labeled "renal parenchyma deep margin final" and consists of a 1.4 x 0.3 x 0.2 cm portion of kidney. The deep margin is inked black. The tissue is sectioned (perpendicular sections), frozen, and entirely submitted in FSE1.

Source: NCI Genomic Data Commons file 66ec3c94-dfe7-4cbf-8ec1-8d820ea51500 (TCGA-2Z-A9JI.D1CF1667-BA52-49CC-B2F5-132DB82967AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).